Somatic mutation profile of tumor specimen TCGA-D3-A51J-06A (aliquot TCGA-D3-A51J-06A-11D-A25O-08) from TCGA case TCGA-D3-A51J, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 27.3 years (9,956 days).
Specimen TCGA-D3-A51J-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b07f46fa-9ba7-4c66-9c86-2038813a9697.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A51J-10A (Blood Derived Normal), aliquot TCGA-D3-A51J-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2a41d8f-c891-419a-9353-0e025d36fddc

The open-access MAF lists 533 somatic variants for this specimen: 357 protein-altering or splice-affecting, 163 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 322, Silent 163, Nonsense Mutation 22, Splice Site 8, Intron 7, Splice Region 4, RNA 3, 5'UTR 1, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.151-2A>T p.X51_splice | Splice Site (SNP) | VAF 12/21 reads (57%) | hotspot (GDC flag); catalogued as CS014762, CS127043, COSV58692638, COSV58692823, COSV58707376; called by muse, mutect2, varscan2
- CRNKL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057519885, COSV55618331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNT1 | c.728G>A p.R243Q (on ENST00000488444; = p.R262Q on NM_020822.3) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1554771469, CM159165, COSV53706435; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TBX5 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs483353129, COSV59863409; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.3221G>A p.W1074* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as rs1064797138, COSV56403634; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV53979611; called by muse, mutect2, varscan2
- ACADS | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV54369683; called by muse, mutect2, varscan2
- ACSL3 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV62483762; called by muse, mutect2, varscan2
- ACSL5 | c.1271C>T p.S424F (on ENST00000354273; = p.S480F on NM_016234.3) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778881983, COSV61132361; called by muse, mutect2, varscan2
- ADAM18 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.163); catalogued as COSV55851341; called by muse, mutect2, varscan2
- ADAM29 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63665931; called by muse, mutect2, varscan2
- ADAMTS8 | c.2185G>A p.D729N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV57292653; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755886007, COSV65895608; called by muse, mutect2, varscan2
- ADGRL2 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV54678387; called by muse, mutect2, varscan2
- ADH7 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52922140; called by muse, mutect2, varscan2
- AEBP2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV56865071; called by muse, mutect2, varscan2
- AGBL1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV66857190; called by muse, mutect2, varscan2
- ANAPC4 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs543616759, COSV100193854; called by muse, mutect2, varscan2
- ANGPT1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs757109289, COSV52434162; called by muse, mutect2, varscan2
- ANK1 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs745689377, COSV55888705; called by muse, mutect2, varscan2
- ANKRD13A | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs761738913, COSV55677426; called by muse, mutect2, varscan2
- ANO5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as COSV100202198, COSV61088048; called by muse, mutect2, varscan2
- AP2B1 | c.1797-1G>A p.X599_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52001524; called by muse, mutect2, varscan2
- APOB | c.9032G>A p.G3011E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs772266350, COSV51944689; called by muse, mutect2, varscan2
- AQR | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV50042666; called by muse, mutect2
- ARHGAP36 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.994); catalogued as COSV52266219; called by muse, mutect2, varscan2
- ARID5A | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62591482; called by muse, mutect2
- ASRGL1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV57125591; called by muse, mutect2, varscan2
- B4GALNT2 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55927398; called by muse, mutect2, varscan2
- B4GAT1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV60820419; called by muse, mutect2, varscan2
- BAIAP3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs762606225, COSV60982323; called by muse, mutect2
- BAZ2A | c.4372C>T p.R1458* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1188565161, COSV51640440; called by muse, mutect2, varscan2
- BAZ2B | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.235); catalogued as rs368174044; called by muse, mutect2, varscan2
- BMP2 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs267606060, COSV66578753; called by muse, mutect2
- BMP5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702572; called by muse, mutect2, varscan2
- BMPER | c.1562A>C p.D521A | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV51826135; called by muse, mutect2, varscan2
- BNIPL | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs141131792; called by muse, mutect2, varscan2
- C2orf78 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.97); catalogued as COSV68518508; called by muse, mutect2, varscan2
- C4orf19 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52649829; called by muse, mutect2, varscan2
- C8orf76 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as rs751811971, COSV52691167; called by muse, mutect2, varscan2
- CA10 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV53361251; called by muse, mutect2, varscan2
- CAMKMT | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV65927818; called by muse, mutect2, varscan2
- CAPN6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs766454026, COSV60693679; called by muse, mutect2, varscan2
- CAT | c.1494C>A p.D498E | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV53812258; called by muse, mutect2, varscan2
- CATSPERB | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1566736229, COSV56430895; called by muse, mutect2, varscan2
- CCDC148 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV51766292; called by muse, mutect2, varscan2
- CCDC88B | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1368935751, COSV57267199; called by muse, mutect2
- CCNG2 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV60354308; called by muse, mutect2
- CD163 | c.1497G>C p.W499C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63135360; called by muse, mutect2, varscan2
- CD1D | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1453004060, COSV63809510; called by muse, mutect2, varscan2
- CDH16 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV55338364; called by muse, mutect2, varscan2
- CDH18 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs754373165, COSV56943133; called by muse, mutect2, varscan2
- CDH4 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV64665760; called by muse, mutect2, varscan2
- CEACAM3 | c.628-1G>A p.X210_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV55762564; called by muse, mutect2, varscan2
- CFAP100 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV61503859; called by muse, mutect2, varscan2
- CFAP47 | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs748173415, COSV100545776, COSV57971660; called by muse, mutect2, varscan2
- CHAF1A | c.1656G>C p.R552S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as COSV56674744; called by muse, mutect2, varscan2
- CHRD | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.019); catalogued as COSV52610562, COSV99200273; called by muse, mutect2, varscan2
- CLPTM1L | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57991717; called by muse, mutect2, varscan2
- CMTR1 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs201399989, COSV65089295; called by muse, mutect2, varscan2
- CMYA5 | c.9835G>A p.E3279K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs760219385, COSV71407883, COSV71408891; called by muse, mutect2, varscan2
- COL21A1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV55172502; called by muse, mutect2
- COL21A1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55155721, COSV55175198; called by muse, mutect2, varscan2
- COL22A1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV57343726; called by muse, mutect2, varscan2
- COL28A1 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68083517; called by muse, mutect2, varscan2
- COL4A3 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192698671, COSV67417684; called by muse, mutect2, varscan2
- COL4A4 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV61634465; called by muse, mutect2, varscan2
- COL7A1 | c.8065G>A p.G2689R | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748940147, CM060933, CM111402, COSV56476006; called by muse, mutect2, varscan2
- COLEC12 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs905694157, COSV68369756; called by muse, mutect2, varscan2
- CORO2A | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.531); catalogued as COSV59664004; called by muse, mutect2, varscan2
- CPSF6 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57016742; called by muse, mutect2, varscan2
- CSMD3 | c.3020C>T p.T1007M (on ENST00000297405 / NM_001363185.1; = p.T903M on NM_052900.3) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs374975849, COSV52271239, COSV99845647; called by muse, mutect2, varscan2
- CTAGE15 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV101372127; called by mutect2, varscan2
- CTNNA2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58166177; called by muse, mutect2, varscan2
- CXCR5 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV52687270; called by muse, mutect2, varscan2
- CYP24A1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53775763; called by muse, mutect2, varscan2
- CYTIP | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs769091432, COSV51634836; called by muse, mutect2, varscan2
- DCC | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as rs1406742141, COSV100498666, COSV59088400, COSV59131458; called by muse, mutect2, varscan2
- DEPDC5 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as rs200461139, COSV56704512; called by muse, mutect2, varscan2
- DGKG | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760665571, COSV53969104; called by muse, mutect2, varscan2
- DISP2 | c.2587G>A p.D863N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs1228470176, COSV51130724; called by muse, mutect2, varscan2
- DNAH11 | c.5033G>A p.G1678E | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV60968043; called by muse, mutect2, varscan2
- DNAH3 | c.10454T>G p.V3485G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV54537292; called by muse, mutect2, varscan2
- DNAH3 | c.10361G>A p.W3454* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV54537310; called by muse, mutect2, varscan2
- DNAH8 | c.12311G>A p.W4104* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV59465785; called by muse, mutect2, varscan2
- DNAH9 | c.6868G>A p.A2290T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs867983875, COSV52363590; called by muse, mutect2
- DNMT1 | c.3737C>T p.S1246F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61581620; called by muse, mutect2, varscan2
- DNMT3A | c.2598G>A p.R866= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99260119; called by muse, mutect2, varscan2
- DNMT3A | c.2598-1G>A p.X866_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as rs766506181, COSV53060314, COSV99261824; called by muse, mutect2, varscan2
- DNMT3B | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV52420933; called by muse, mutect2, varscan2
- DSCAM | c.4415G>A p.G1472E | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68026958; called by muse, mutect2, varscan2
- DSCAML1 | c.1955C>T p.A652V (on ENST00000321322; = p.A592V on NM_020693.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs751688355, COSV58397344; called by muse, mutect2, varscan2
- DYDC1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV64731755; called by muse, mutect2
- E4F1 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV57040275; called by muse, mutect2, varscan2
- EFCAB5 | c.3799G>A p.D1267N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562656184, COSV57933675; called by muse, mutect2, varscan2
- EIF2AK3 | c.3293C>T p.S1098L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs770232594, COSV57546895; called by muse, mutect2, varscan2
- ELSPBP1 | c.355+1G>A p.X119_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as rs768818411, COSV60414433; called by muse, mutect2, varscan2
- ERAP2 | c.1486T>A p.W496R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65940699; called by muse, mutect2, varscan2
- ESRRG | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63171317; called by muse, mutect2, varscan2
- EZH1 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70548736; called by muse, mutect2, varscan2
- EZH1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101331344; called by muse, mutect2, varscan2
- FAM234B | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52196221; called by muse, varscan2
- FAM83A | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.246); catalogued as COSV52686586; called by muse, mutect2
- FAM83B | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60924609; called by muse, mutect2, varscan2
- FAM83G | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58760289; called by muse, mutect2, varscan2
- FAM8A1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV52582363; called by muse, mutect2
- FAT4 | c.14659G>A p.G4887R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs867281063, COSV58698554; called by muse, mutect2, varscan2
- FBN3 | c.7753C>T p.R2585C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs760490060, COSV54459122; called by muse, mutect2, varscan2
- FBXO38 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57029694; called by muse, mutect2, varscan2
- FBXO46 | c.1276_1287del p.D426_A429del | In Frame Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs745459137; called by mutect2, varscan2
- FER1L6 | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs145959839, COSV67550472; called by muse, mutect2, varscan2
- FES | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.388); catalogued as rs767265676, COSV51578280; called by muse, mutect2, varscan2
- FGF5 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56891155; called by muse, mutect2, varscan2
- FLG2 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 43/191 reads (23%) | catalogued as COSV66171010; called by muse, mutect2, varscan2
- FLT4 | c.4004G>A p.S1335N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); catalogued as COSV56116411; called by muse, mutect2, varscan2
- FMO1 | c.627G>A p.K209= | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as COSV61446883; called by muse, mutect2, varscan2
- FPR2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV60673900; called by muse, mutect2, varscan2
- FSTL4 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54778644; called by muse, mutect2, varscan2
- FSTL5 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs1223710759, COSV60213057; called by muse, mutect2, varscan2
- GABRB2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50904046; called by muse, mutect2, varscan2
- GABRB3 | c.1394T>G p.L465* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV54672511, COSV54674652; called by muse, mutect2, varscan2
- GABRP | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54664333; called by muse, mutect2, varscan2
- GABRR1 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV101033781; called by muse, mutect2, varscan2
- GABRR1 | c.899G>A p.W300* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV101033782, COSV101034064; called by muse, mutect2, varscan2
- GAPVD1 | c.3328C>T p.P1110S (on ENST00000394104; = p.P1119S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV52925516; called by muse, mutect2, varscan2
- GCOM1 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449257847, COSV51088722; called by muse, mutect2, varscan2
- GDPD1 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as COSV52383290; called by muse, mutect2, varscan2
- GGA1 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289933, COSV57331057; called by muse, mutect2, varscan2
- GHRHR | c.885G>A p.V295= | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as rs146944568, COSV58196743; called by muse, mutect2, varscan2
- GLYATL2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.105); catalogued as COSV54850813; called by muse, mutect2, varscan2
- GOLGB1 | c.4081C>T p.H1361Y | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs147482666; called by muse, mutect2, varscan2
- GOLGB1 | c.3085C>T p.L1029F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs775738744, COSV61468491; called by muse, mutect2, varscan2
- GPC5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1268970301, COSV65614751; called by muse, mutect2, varscan2
- GPR63 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57739676; called by muse, mutect2, varscan2
- GRB7 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58447420; called by muse, mutect2, varscan2
- GRID2 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs145785994; called by muse, mutect2, varscan2
- GRM2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143196180; called by muse, mutect2, varscan2
- GRXCR1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs569193097, CM153970, COSV67670071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSTA4 | c.415-1G>A p.X139_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV63955838; called by muse, mutect2, varscan2
- HENMT1 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1197211507, COSV64230507; called by muse, mutect2, varscan2
- HEPACAM2 | c.1279C>T p.P427S (on ENST00000394468 / NM_001039372.4; = p.P415S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100506340, COSV59060752; called by muse, mutect2, varscan2
- HNRNPCL1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV58613433; called by muse, mutect2, varscan2
- HPX | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs757050607, COSV56420072; called by muse, mutect2, varscan2
- IGF1R | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV51277250; called by muse, mutect2, varscan2
- IGHV3-13 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs781966487; called by muse, mutect2, varscan2
- IGLC2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.2); catalogued as rs551176080; called by muse, mutect2, varscan2
- IKZF2 | c.1562G>A p.G521E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59581411; called by muse, mutect2, varscan2
- IL18R1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs377457925, COSV52122893; called by muse, mutect2, varscan2
- INAVA | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV66256407; called by muse, mutect2, varscan2
- ITGA1 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV50889359; called by muse, mutect2, varscan2
- ITGBL1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66009937; called by muse, mutect2, varscan2
- ITSN1 | c.2413C>T p.P805S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV66084547; called by muse, mutect2, varscan2
- JAKMIP2 | c.2308C>T p.L770F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54610324; called by muse, mutect2, varscan2
- KIF1B | c.3140C>T p.S1047L (on ENST00000377086 / NM_001365952.1; = p.S1001L on NM_015074.3) | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs267597898, COSV55811951; called by muse, mutect2, varscan2
- KIR3DL1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV58493721; called by muse, mutect2, varscan2
- KLHL31 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100911739; called by muse, mutect2, varscan2
- KLK10 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV59398002; called by muse, mutect2, varscan2
- KLK6 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59566232; called by mutect2, varscan2
- KLKB1 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV52993878; called by muse, mutect2, varscan2
- KMT2D | c.3119C>T p.S1040F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV56466201, COSV99979039; called by muse, mutect2, varscan2
- KMT2D | c.2747C>T p.P916L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs765475926, COSV56466224; called by muse, mutect2, varscan2
- KRT10 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762627487, COSV54090705; called by muse, mutect2, varscan2
- KRT23 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52928382; called by muse, mutect2, varscan2
- KRT74 | c.1389C>A p.I463= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as COSV59772676; called by muse, varscan2
- LAMB4 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52725476; called by muse, mutect2, varscan2
- LIMCH1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374022264; called by muse, mutect2, varscan2
- LPA | c.4957G>A p.E1653K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV60297350; called by muse, mutect2, varscan2
- LRP1B | c.9466G>A p.G3156S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV67251180; called by muse, mutect2, varscan2
- LRP1B | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV67194894; called by muse, mutect2, varscan2
- LRP1B | c.156T>G p.C52W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV67251187; called by muse, mutect2, varscan2
- LRP2 | c.12649G>A p.G4217R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55560502; called by muse, mutect2, varscan2
- LRRK2 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs1350068444, COSV54159202; called by mutect2, varscan2
- LYG2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV60716252; called by muse, mutect2
- LYSMD2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51056979; called by muse, mutect2, varscan2
- MAGEA3 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV64755941; called by muse, mutect2, varscan2
- MAP3K5 | c.2320A>C p.K774Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV62890626; called by muse, mutect2, varscan2
- MARCHF10 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV60889355; called by muse, mutect2, varscan2
- MBD5 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs749574412, COSV68698339; called by muse, mutect2, varscan2
- MEGF11 | c.2018G>A p.G673E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56546520; called by muse, mutect2, varscan2
- MEIS2 | c.914C>T p.S305F (on ENST00000561208 / NM_170675.5; = p.S292F on NM_002399.3) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54935743; called by muse, mutect2, varscan2
- METTL26 | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57011066; called by muse, mutect2, varscan2
- MICAL2 | c.5641C>T p.H1881Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV56287559; called by muse, mutect2
- MIGA2 | c.488A>C p.E163A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV52977805; called by muse, mutect2
- MOCS3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV54865881, COSV54867244; called by muse, mutect2, varscan2
- MOGAT2 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV52220751; called by muse, mutect2, varscan2
- MOS | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61336712; called by muse, mutect2, varscan2
- MUC16 | c.26266C>T p.P8756S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.047); catalogued as rs756980327, COSV67467850; called by muse, mutect2, varscan2
- MUC16 | c.21580G>A p.E7194K | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV67453099; called by muse, mutect2, varscan2
- MUC16 | c.20914C>T p.L6972F | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV67480274; called by muse, mutect2, varscan2
- MUC16 | c.10142C>T p.S3381L | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67457343; called by muse, mutect2, varscan2
- MUC17 | c.7990G>T p.V2664L | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.417); catalogued as COSV60286428, COSV60296569; called by muse, mutect2, varscan2
- MUC17 | c.11378C>T p.S3793L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV60287746; called by muse, mutect2, varscan2
- MUC5B | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101500053, COSV71594250; called by muse, mutect2, varscan2
- MXRA5 | c.6670C>T p.R2224* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV54229182; called by muse, mutect2, varscan2
- MXRA5 | c.3782C>T p.P1261L | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV54237671; called by muse, mutect2, varscan2
- MXRA5 | c.3781C>T p.P1261S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV99476038; called by muse, mutect2, varscan2
- MYH1 | c.5304G>A p.M1768I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV56853208; called by muse, mutect2, varscan2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- MYH11 | c.2469C>G p.C823W | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259591, COSV55562270; called by muse, mutect2, varscan2
- MYH14 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.388); catalogued as COSV51825358; called by muse, mutect2
- MYH2 | c.4984C>T p.H1662Y | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs867066856, COSV55443562; called by muse, mutect2, varscan2
- MYH2 | c.2840G>A p.R947K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as COSV99819456; called by muse, mutect2, varscan2
- MYH3 | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56867803; called by muse, mutect2, varscan2
- MYO15A | c.9894G>A p.W3298* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as COSV52761325; called by muse, mutect2, varscan2
- MYO7B | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV67347865; called by muse, mutect2, varscan2
- MYOM3 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV58397354; called by muse, mutect2, varscan2
- N4BP2L2 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57229277; called by muse, mutect2, varscan2
- NCOA6 | c.4145C>T p.A1382V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV62865947; called by muse, mutect2, varscan2
- NCR1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV52557661; called by muse, mutect2, varscan2
- NDUFC2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147426758; called by muse, mutect2, varscan2
- NEBL | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV65802590; called by muse, mutect2, varscan2
- NLRP10 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs77351963, COSV60780000; called by muse, mutect2, varscan2
- NLRP12 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV60751070; called by muse, mutect2, varscan2
- NPY1R | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV56713188, COSV56715513; called by muse, mutect2, varscan2
- OBSCN | c.7066G>A p.E2356K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs746898810, COSV52802248; called by muse, mutect2, varscan2
- OR2B6 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as rs267600922, COSV55129462; called by muse, mutect2, varscan2
- OR2L13 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63547989, COSV63557359; called by muse, mutect2, varscan2
- OR4C3 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778948434, COSV60588150; called by muse, mutect2, varscan2
- OR4D5 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58308367; called by muse, mutect2, varscan2
- OR51A4 | c.358A>T p.M120L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV66749827; called by muse, mutect2, varscan2
- OR51G2 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866332976, COSV58994054; called by muse, mutect2, varscan2
- OR51T1 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV59026853; called by muse, mutect2, varscan2
- OR5F1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV53546525, COSV99558988; called by muse, mutect2, varscan2
- OR5H14 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs370923244; called by muse, mutect2, varscan2
- OR8A1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV104370618, COSV52509404; called by muse, mutect2, varscan2
- OTOGL | c.5761A>C p.M1921L (on ENST00000547103; = p.M1912L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753136159, COSV54020359; called by muse, mutect2, varscan2
- PACS1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs760699901, COSV57696399; called by muse, mutect2, varscan2
- PAK5 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs562732119, COSV62020766; called by muse, mutect2, varscan2
- PARP15 | c.1393C>T p.L465F (on ENST00000464300 / NM_001113523.3; = p.L231F on NM_152615.2) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.116); catalogued as COSV59971812; called by muse, mutect2, varscan2
- PBX3 | c.1130C>T p.T377I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV60734360; called by muse, mutect2
- PCDHA3 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs148196865, COSV63538858; called by muse, mutect2, varscan2
- PCDHB16 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.897); catalogued as rs782092823, COSV53367130; called by muse, mutect2, varscan2
- PCDHGB5 | c.395A>T p.K132I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53992390; called by muse, mutect2, varscan2
- PCDHGB7 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53992398; called by muse, mutect2, varscan2
- PEG3 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV55641040; called by muse, mutect2, varscan2
- PHF5A | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV53440089; called by muse, mutect2, varscan2
- PI4KA | c.4655C>T p.P1552L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55404034; called by muse, varscan2
- PKHD1L1 | c.5273C>T p.S1758F | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV65736818, COSV65745021; called by muse, mutect2, varscan2
- PKHD1L1 | c.5758G>A p.G1920R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV65748158; called by muse, mutect2, varscan2
- PKP2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV50739019; called by muse, mutect2, varscan2
- PNPLA6 | c.1561C>T p.P521S (on ENST00000414982 / NM_001166111.2; = p.P473S on NM_006702.5) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.556); catalogued as COSV55381985; called by muse, mutect2, varscan2
- POU3F3 | c.1103T>G p.L368R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63722147; called by muse, mutect2, varscan2
- PPARA | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1389815337, COSV53079487; called by muse, mutect2, varscan2
- PPFIA2 | c.3622G>A p.G1208R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV61022917; called by muse, mutect2, varscan2
- PRDM2 | c.2690A>T p.N897I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as COSV52451445; called by muse, mutect2, varscan2
- PREX2 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138740482, COSV55765054, COSV55787471; called by muse, mutect2, varscan2
- PRKACG | c.476A>C p.H159P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55253192, COSV99599282; called by muse, mutect2, varscan2
- PRKG1 | c.947G>C p.R316T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64774570; called by muse, mutect2, varscan2
- PRR12 | c.983C>T p.P328L (on ENST00000615927; = p.P1149L on NM_020719.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV69818858; called by muse, mutect2
- PRR16 | c.376C>T p.P126S (on ENST00000407149 / NM_001300783.2; = p.P103S on NM_016644.2) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65405524; called by muse, mutect2, varscan2
- PRR16 | c.377C>T p.P126L (on ENST00000407149 / NM_001300783.2; = p.P103L on NM_016644.2) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101086473, COSV65394609; called by muse, mutect2, varscan2
- PRR23B | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61494392; called by muse, mutect2, varscan2
- PRRC2A | c.4055G>A p.G1352E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV65688116; called by muse, mutect2, varscan2
- PRSS16 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs764893995, COSV57916169; called by muse, mutect2, varscan2
- PSG4 | c.1178C>A p.A393D | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.356); catalogued as COSV54938137, COSV54939140; called by muse, mutect2, varscan2
- PTPRR | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV51739741; called by muse, mutect2, varscan2
- PUS10 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs781267971, COSV100369426; called by muse, varscan2
- PWWP3B | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV61800976; called by muse, mutect2, varscan2
- PXDNL | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62493703; called by muse, mutect2, varscan2
- RAB3GAP2 | c.2953A>T p.M985L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62785770; called by muse, mutect2, varscan2
- RAB8A | c.403C>G p.R135G | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV56290763, COSV56292365; called by muse, mutect2, varscan2
- RELN | c.8358G>A p.W2786* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV58999710; called by muse, mutect2, varscan2
- REST | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV58361936; called by muse, mutect2, varscan2
- RGS5 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774978465, COSV58352625; called by muse, mutect2, varscan2
- RIN1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.435); catalogued as COSV60927850; called by muse, mutect2, varscan2
- RNF112 | c.1677G>A p.M559I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV71327092; called by muse, mutect2, varscan2
- ROBO2 | c.3244C>T p.L1082F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.643); catalogued as rs1320335485, COSV59926321; called by muse, mutect2, varscan2
- ROBO3 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866321323, COSV67301841; called by muse, mutect2, varscan2
- RPP40 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs199946178, COSV60292586; called by muse, mutect2, varscan2
- RPTN | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs762672828, COSV60168245; called by muse, mutect2, varscan2
- RUFY2 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1188217519, COSV66253017; called by muse, mutect2, varscan2
- SALL1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV51754140; called by muse, mutect2, varscan2
- SCN11A | c.5200G>A p.E1734K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56573265; called by muse, mutect2, varscan2
- SENP7 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs747057180, COSV58607892; called by muse, mutect2
- SGO2 | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV63416461; called by muse, mutect2, varscan2
- SH3TC1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs774779667, COSV55287187; called by muse, mutect2, varscan2
- SLC17A6 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV54139004; called by muse, mutect2, varscan2
- SLC22A9 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs1408469797, COSV54166852; called by muse, mutect2, varscan2
- SLC25A11 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52591038; called by muse, mutect2, varscan2
- SLC25A17 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54352092; called by muse, mutect2, varscan2
- SLC25A51 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1341101846, COSV99643278; called by muse, mutect2, varscan2
- SLC8A3 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233142203, COSV63524375; called by muse, mutect2, varscan2
- SLIT2 | c.3892G>A p.G1298R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.255); catalogued as COSV56584534; called by muse, mutect2, varscan2
- SLITRK3 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.465); catalogued as COSV53851076; called by muse, mutect2, varscan2
- SLX4 | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV53566392; called by muse, mutect2, varscan2
- SNRPN | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV57598966; called by muse, mutect2, varscan2
- SORL1 | c.3250C>T p.R1084C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52757172; called by muse, mutect2, varscan2
- SOX10 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs1367116894, COSV61005801; called by muse, mutect2, varscan2
- SPDYC | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV65865496; called by muse, mutect2, varscan2
- SPEF2 | c.2714C>T p.S905F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV61551339; called by muse, mutect2, varscan2
- SPEG | c.3644C>T p.P1215L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56675368; called by muse, mutect2, varscan2
- STAG3 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV57933023; called by muse, mutect2, varscan2
- STK11IP | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55252956; called by mutect2, varscan2
- STK24 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64823343; called by muse, mutect2, varscan2
- SUN5 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV62181257; called by muse, mutect2, varscan2
- SUSD2 | c.2014A>C p.N672H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV64204737; called by muse, mutect2, varscan2
- SYNGR2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV56746241; called by muse, mutect2, varscan2
- SYNJ2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424035186, COSV62899023; called by muse, mutect2
- SYNPO2 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV61114508; called by muse, mutect2, varscan2
- SYT9 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as rs554348328, COSV59615726; called by muse, mutect2, varscan2
- TBC1D32 | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51548993; called by muse, mutect2, varscan2
- TCAIM | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV61241741; called by muse, mutect2, varscan2
- TCERG1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57039822; called by muse, mutect2, varscan2
- TCFL5 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as rs528649129, COSV53898433; called by muse, mutect2, varscan2
- TDRD1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV52593348; called by muse, mutect2, varscan2
- TENM1 | c.7984G>A p.E2662K | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64434051; called by muse, mutect2, varscan2
- TENM4 | c.6662G>A p.G2221E | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1479986304, COSV53650364, COSV99577940; called by muse, mutect2, varscan2
- TGFB1 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55724379, COSV55725937; called by muse, mutect2, varscan2
- THOC2 | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55551369; called by muse, mutect2, varscan2
- TJP3 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs1229047013, COSV53664345, COSV53665047; called by muse, mutect2, varscan2
- TLR9 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV62347705; called by muse, mutect2, varscan2
- TNFRSF8 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.398); catalogued as COSV55798799; called by muse, mutect2, varscan2
- TPH1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs764562976, COSV51456869, COSV51459256; called by muse, mutect2, varscan2
- TPTE2 | c.1102G>A p.E368K (on ENST00000400230 / NM_199254.2; = p.E291K on NM_130785.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV55025229; called by muse, mutect2, varscan2
- TRAPPC3 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415873534, COSV64264466; called by muse, mutect2, varscan2
- TRHDE | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53855653; called by muse, mutect2, varscan2
- TRHR | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs751896079, COSV61235589; called by muse, mutect2, varscan2
- TRIM58 | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1346369186, COSV63571481; called by muse, mutect2, varscan2
- TRIML2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV58718093; called by muse, mutect2, varscan2
- TRIO | c.3067-1G>A p.X1023_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as COSV60089165; called by muse, mutect2, varscan2
- TRPM4 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99419189; called by muse, mutect2, varscan2
- TTC24 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV63998165; called by muse, mutect2, varscan2
- TTN | c.69605A>T p.N23202I (on ENST00000591111; = p.N15778I on NM_003319.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen probably damaging (0.999); catalogued as COSV60207743; called by muse, mutect2, varscan2
- TTN | c.22008G>A p.W7336* (on ENST00000591111; = p.W6409* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV60140445; called by muse, mutect2, varscan2
- TTN | c.16369G>A p.D5457N (on ENST00000591111; = p.D4530N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | PolyPhen benign (0.001); catalogued as rs752660722, COSV60026502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.8471C>T p.P2824L (on ENST00000591111; = p.P2778L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | PolyPhen probably damaging (0.976); catalogued as COSV60207792; called by muse, mutect2, varscan2
- TUBD1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760435470, COSV57873537; called by muse, mutect2, varscan2
- UGT1A5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs1357928110, COSV59380995; called by muse, mutect2, varscan2
- USP26 | c.2121T>G p.F707L | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.42); PolyPhen benign (0.173); catalogued as COSV63709257; called by muse, mutect2, varscan2
- USP29 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV54144680; called by muse, mutect2, varscan2
- USP34 | c.7720T>G p.C2574G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV68403890; called by muse, mutect2, varscan2
- VPS13A | c.9512C>T p.S3171F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.212); catalogued as COSV64333660; called by muse, mutect2, varscan2
- VPS53 | c.670C>T p.P224S (on ENST00000571805 / NM_001366253.2; = p.P195S on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52134171; called by muse, mutect2, varscan2
- WDR24 | c.1873G>A p.G625S (on ENST00000248142; = p.G495S on NM_032259.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs776521521, COSV50200539; called by muse, mutect2, varscan2
- WDR74 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53932689; called by muse, mutect2, varscan2
- XDH | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.627); catalogued as rs763648123, COSV65150178; called by muse, mutect2, varscan2
- XDH | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65150183; called by muse, mutect2, varscan2
- XYLT1 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); catalogued as rs757158375, COSV54491181; called by muse, mutect2, varscan2
- ZBBX | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs1433485236, COSV56795764; called by muse, mutect2
- ZBTB20 | c.752C>T p.S251F (on ENST00000474710 / NM_001164342.2; = p.S178F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV61859492; called by muse, mutect2, varscan2
- ZBTB39 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV55630101; called by muse, mutect2, varscan2
- ZC3H12C | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs1482210667, COSV53710937, COSV53711603; called by muse, mutect2, varscan2
- ZFPM2 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV68288214; called by muse, mutect2, varscan2
- ZFPM2 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101023313, COSV65874828; called by muse, varscan2
- ZNF226 | c.1825C>T p.H609Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56197356; called by muse, mutect2, varscan2
- ZNF251 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs756744977, COSV52958414; called by muse, mutect2, varscan2
- ZNF318 | c.3772C>T p.Q1258* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV100545999; called by muse, mutect2, varscan2
- ZNF354A | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV59984119; called by muse, mutect2, varscan2
- ZNF532 | c.2818G>A p.D940N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60174566; called by muse, mutect2, varscan2
- ZNF831 | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as COSV64043025; called by muse, mutect2, varscan2
- ZNF878 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV72156066; called by muse, mutect2, varscan2
- ZSCAN4 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs1444052035, COSV56594064; called by muse, mutect2, varscan2
- MAGEB6B | c.279T>A p.S93R | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- RBMY1E | c.1388T>G p.V463G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.187); called by mutect2, varscan2
- SPATA31A1 | c.2789G>A p.S930N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); called by mutect2, varscan2
- TPST2 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2
- A4GNT | c.999G>A p.G333= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV52629655; called by muse, mutect2, varscan2
- ABI3 | c.369G>A p.K123= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs1426818944, COSV56800914; called by muse, mutect2, varscan2
- ACTL7B | c.1071G>A p.R357= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs901751354, COSV65927768; called by muse, mutect2, varscan2
- ADAM11 | c.1941C>T p.S647= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV52346211; called by muse, mutect2, varscan2
- ADAMTS16 | c.1254G>A p.T418= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs367971660; called by muse, mutect2, varscan2
- ADAMTS18 | c.1350G>A p.G450= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV51419864; called by muse, mutect2, varscan2
- ADCY8 | c.1756T>C p.L586= | Silent (SNP) | VAF 71/164 reads (43%) | catalogued as COSV53918071; called by muse, mutect2, varscan2
- ANAPC4 | c.30C>T p.S10= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV59543070; called by muse, mutect2, varscan2
- ANK3 | c.11211C>T p.G3737= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV55070817; called by muse, mutect2, varscan2
- ARFGEF3 | c.5829C>T p.F1943= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52464234; called by muse, mutect2, varscan2
- ARHGAP30 | c.2508G>A p.K836= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV63518042; called by muse, mutect2, varscan2
- ARID5B | c.1813C>T p.L605= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV54425855; called by muse, mutect2, varscan2
- ARPP21 | c.1176G>A p.R392= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV51803288; called by muse, mutect2, varscan2
- ASXL3 | c.3951C>T p.S1317= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV52473329; called by muse, mutect2, varscan2
- ATP9A | c.1902G>A p.T634= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs190370313; called by muse, mutect2, varscan2
- B4GALT2 | c.945G>A p.K315= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV58844948; called by muse, mutect2, varscan2
- BACH2 | c.702C>T p.Y234= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs748269096, COSV57601382; called by muse, mutect2, varscan2
- BNIPL | c.543C>T p.F181= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99764546; called by muse, mutect2, varscan2
- BPIFB4 | c.387A>G p.A129= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as rs1291376079, COSV64951797; called by muse, mutect2, varscan2
- BRINP1 | c.2139G>C p.G713= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- C9orf64 | c.39C>T p.F13= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV59032884; called by muse, mutect2, varscan2
- CD1C | c.558C>T p.P186= | Silent (SNP) | VAF 63/308 reads (20%) | catalogued as rs377534018, COSV63807048; called by muse, mutect2, varscan2
- CD300LG | c.981G>A p.S327= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs756841085, COSV53224939; called by muse, mutect2, varscan2
- CDX1 | c.543C>T p.I181= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV51568886; called by muse, mutect2, varscan2
- CHST12 | c.1143C>T p.F381= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV51676850; called by muse, mutect2, varscan2
- CHTF18 | c.1893A>G p.R631= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV50210769; called by muse, mutect2, varscan2
- CMTR1 | c.396C>T p.L132= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs755809917, COSV65091140; called by muse, mutect2, varscan2
- CPXM2 | c.1155C>T p.G385= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV53866953; called by muse, mutect2, varscan2
- CR2 | c.480C>T p.I160= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV65506208; called by muse, mutect2, varscan2
- CREBZF | c.304C>T p.L102= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV52630155; called by muse, mutect2, varscan2
- CTNNAL1 | c.1794G>A p.R598= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV57704366; called by muse, mutect2, varscan2
- CYP3A43 | c.381G>A p.K127= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV55937108; called by muse, mutect2, varscan2
- DCSTAMP | c.1113C>T p.F371= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV52576093; called by muse, mutect2, varscan2
- DIS3 | c.2733C>T p.I911= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100899922, COSV66707369; called by muse, mutect2, varscan2
- DNAH11 | c.12015T>C p.L4005= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV60968054; called by muse, varscan2
- DOT1L | c.2061C>T p.A687= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101288537; called by muse, mutect2, varscan2
- DPYS | c.1359C>T p.F453= | Silent (SNP) | VAF 86/209 reads (41%) | catalogued as COSV100679475, COSV60911365; called by muse, mutect2, varscan2
- DSC3 | c.450C>T p.G150= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV64574202; called by muse, mutect2, varscan2
- DYDC2 | c.21G>A p.K7= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV55472931; called by muse, mutect2, varscan2
- ELAVL4 | c.201G>A p.G67= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV63917842; called by muse, mutect2, varscan2
- ELOVL7 | c.597G>A p.K199= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV70918387; called by muse, mutect2, varscan2
- FABP3 | c.270G>A p.G90= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV60003160; called by muse, mutect2, varscan2
- FAM234B | c.1593C>T p.S531= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV52196210; called by muse, varscan2
- FAT4 | c.12954A>C p.T4318= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV58698548; called by muse, mutect2, varscan2
- FBN3 | c.3951C>T p.F1317= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs779316238, COSV54457222; called by muse, varscan2
- FHOD3 | c.3075C>T p.I1025= (on ENST00000359247 / NM_001281739.3; = p.I1042= on NM_025135.5) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV57181244; called by muse, mutect2, varscan2
- FRG2C | c.9G>A p.K3= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- GAK | c.948C>T p.I316= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs374345324, COSV58507210; called by muse, mutect2, varscan2
- GCC2 | c.2034A>G p.E678= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV59178429; called by muse, mutect2, varscan2
- GIMAP8 | c.1680G>A p.A560= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as rs1203845409, COSV56229956; called by muse, mutect2, varscan2
- GIPR | c.516C>T p.I172= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV54425324; called by muse, mutect2, varscan2
- GPX5 | c.558C>T p.F186= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV69079594; called by muse, mutect2, varscan2
- GRB7 | c.189C>T p.S63= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV58448070; called by muse, mutect2, varscan2
- GRIA3 | c.1434G>A p.G478= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV52059989; called by muse, mutect2, varscan2
- GRK6 | c.693G>A p.A231= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs766856261, COSV62683558; called by muse, mutect2, varscan2
- GSDME | c.921G>A p.Q307= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs199521210, COSV61652472; called by muse, mutect2, varscan2
- IGHM | c.876G>A p.E292= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.183G>A p.G61= | Silent (SNP) | VAF 37/234 reads (16%) | catalogued as rs782257798; called by muse, mutect2, varscan2
- IGKV3-15 | c.174G>A p.Q58= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs779514645; called by muse, mutect2, varscan2
- IL20RA | c.531C>T p.S177= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV57359521; called by muse, mutect2, varscan2
- ITGAM | c.939C>T p.F313= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV54939882; called by muse, mutect2, varscan2
- ITIH1 | c.273C>T p.I91= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV56257017; called by muse, mutect2, varscan2
- KANSL1 | c.181C>T p.L61= | Silent (SNP) | VAF 17/170 reads (10%) | catalogued as COSV99294150; called by muse, mutect2, varscan2
- KANSL1 | c.180C>T p.S60= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as COSV99294151; called by muse, mutect2, varscan2
- KATNIP | c.3753C>T p.S1251= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs1361220477, COSV55187050; called by muse, mutect2, varscan2
- KBTBD8 | c.300G>A p.S100= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs151133801; called by muse, mutect2, varscan2
- KCNC3 | c.1293C>T p.F431= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs752090228, COSV65386742; called by muse, mutect2, varscan2
- KIF1A | c.3309C>T p.F1103= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57495657; called by muse, mutect2
- KIF21B | c.2466G>T p.L822= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59762373; called by muse, varscan2
- KIF3C | c.1830C>T p.I610= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53100827; called by muse, mutect2, varscan2
- KLHL31 | c.573C>T p.A191= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100911740; called by muse, mutect2, varscan2
- KNTC1 | c.3378G>A p.L1126= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV61082229; called by muse, mutect2, varscan2
- KPRP | c.669C>T p.S223= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV64221949, COSV64222384; called by muse, mutect2, varscan2
- KRT33B | c.672C>T p.V224= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV52441756; called by muse, mutect2, varscan2
- KRT40 | c.459G>A p.T153= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs778363055, COSV66696643; called by muse, mutect2, varscan2
- LEPR | c.1971G>A p.E657= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV60759737; called by muse, mutect2
- LPA | c.3429G>A p.T1143= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs767234041, COSV60306169; called by muse, mutect2, varscan2
- LRRIQ3 | c.1095G>A p.K365= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV63044119; called by muse, mutect2, varscan2
- LRRIQ4 | c.384C>T p.T128= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1217636845, COSV61618871; called by muse, mutect2, varscan2
- LYST | c.4761C>T p.F1587= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV67710735; called by muse, mutect2, varscan2
- LYST | c.315C>T p.I105= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV67710740; called by muse, mutect2, varscan2
- MAP2K5 | c.1056G>A p.G352= | Silent (SNP) | VAF 34/128 reads (27%) | catalogued as COSV51612989; called by muse, mutect2, varscan2
- MC3R | c.381C>T p.S127= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs768973003, COSV54762947; called by muse, mutect2, varscan2
- MGAM | c.3742C>T p.L1248= | Silent (SNP) | VAF 117/262 reads (45%) | catalogued as COSV72075166; called by muse, mutect2, varscan2
- MIDEAS | c.990C>T p.A330= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV54096979; called by muse, mutect2
- MRGPRF | c.723C>T p.I241= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV57995841; called by muse, mutect2
- MRTFB | c.2040C>T p.I680= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV57959820; called by muse, mutect2, varscan2
- MXRA5 | c.4578G>A p.K1526= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV54243134; called by muse, mutect2, varscan2
- MXRA5 | c.2331G>A p.Q777= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV54243153; called by muse, mutect2, varscan2
- MYH1 | c.225C>T p.D75= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV55443553; called by muse, mutect2, varscan2
- MYH11 | c.1566C>T p.I522= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs541905355, COSV55561912, COSV55564671; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH13 | c.102C>T p.S34= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52836238; called by muse, mutect2, varscan2
- MYH3 | c.3516C>T p.F1172= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs954100587, COSV56867790; called by muse, mutect2, varscan2
- MYO16 | c.1389G>A p.G463= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV51779026; called by muse, mutect2, varscan2
- NEB | c.243C>T p.F81= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV51368560, COSV51438946; called by muse, mutect2, varscan2
- NEFH | c.1539G>A p.E513= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV60215903, COSV60218889; called by muse, mutect2, varscan2
- NEUROD4 | c.708C>T p.S236= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1362982769, COSV54470759; called by muse, mutect2, varscan2
- NISCH | c.4473G>A p.E1491= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58740354; called by muse, mutect2, varscan2
- NLRP12 | c.1686C>T p.F562= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV60751043; called by muse, mutect2, varscan2
- NLRP12 | c.12C>A p.T4= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100145167, COSV60751093; called by muse, mutect2, varscan2
- NLRP5 | c.2667C>T p.I889= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs267605709, COSV66764363; called by muse, mutect2, varscan2
- NOB1 | c.678C>T p.V226= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52061520; called by muse, mutect2, varscan2
- NTHL1 | c.651T>A p.V217= (on ENST00000219066; = p.V209= on NM_002528.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV54593666; called by muse, mutect2
- NTRK3 | c.1350C>T p.F450= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV58122720; called by muse, mutect2, varscan2
- OAS3 | c.3202C>T p.L1068= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57447563; called by muse, mutect2, varscan2
- OR10A5 | c.654C>T p.S218= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs560346954, COSV55055136; called by muse, mutect2, varscan2
- OR2L3 | c.102C>T p.F34= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as rs747288930, COSV63455844; called by muse, mutect2, varscan2
- OR2M7 | c.132C>T p.I44= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as COSV58739169, COSV58741114, COSV99049579; called by muse, mutect2, varscan2
- OR2T12 | c.492C>T p.F164= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV58778563; called by muse, mutect2, varscan2
- OR4C12 | c.597G>A p.V199= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV58860416; called by muse, mutect2, varscan2
- OR8B3 | c.231C>T p.F77= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV63541981; called by muse, mutect2, varscan2
- OR8K5 | c.279C>T p.S93= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs777172595, COSV100537200, COSV57890037, COSV57890925; called by muse, mutect2, varscan2
- PATJ | c.4521G>A p.Q1507= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV57166272, COSV57167341; called by muse, mutect2, varscan2
- PCDHGA5 | c.1686C>T p.I562= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV53992373; called by muse, mutect2, varscan2
- PDHA2 | c.171G>T p.A57= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV54778605, COSV54780565; called by muse, mutect2, varscan2
- PIWIL3 | c.2266C>T p.L756= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV59996962; called by muse, mutect2, varscan2
- PKP3 | c.1062G>A p.K354= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV58988786; called by muse, mutect2, varscan2
- PRR12 | c.99C>T p.L33= (on ENST00000615927; = p.L854= on NM_020719.3) | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV69818847; called by muse, mutect2
- PSG5 | c.864C>T p.I288= | Silent (SNP) | VAF 43/188 reads (23%) | catalogued as rs376276637; called by muse, mutect2, varscan2
- QRICH2 | c.3603C>T p.T1201= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as rs1242836840, COSV53155659; called by muse, mutect2
- RANBP1 | c.264C>T p.L88= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV59335615; called by mutect2, varscan2
- RBPMS2 | c.453C>T p.S151= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs1370269743, COSV55605213; called by muse, mutect2, varscan2
- SEPTIN10 | c.1050C>T p.A350= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV61781162; called by muse, mutect2, varscan2
- SETD3 | c.510C>T p.S170= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV59285842; called by muse, mutect2, varscan2
- SH3GL2 | c.1053C>T p.P351= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1159966419, COSV101013964, COSV66052819; called by muse, mutect2, varscan2
- SLC22A1 | c.732C>T p.F244= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV61452402; called by muse, mutect2, varscan2
- SLC25A48 | c.618C>T p.I206= (on ENST00000650267; = p.I152= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV50850202; called by muse, mutect2, varscan2
- SLC25A51 | c.543C>T p.F181= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1350864186, COSV99643280; called by muse, mutect2, varscan2
- SLC5A7 | c.204C>T p.I68= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV50896091; called by muse, mutect2, varscan2
- SLC8A3 | c.264C>T p.F88= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs778645024, COSV63519068; called by muse, mutect2, varscan2
- SLCO4C1 | c.1140G>A p.K380= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV60518120, COSV60518335; called by muse, mutect2
- SLITRK3 | c.984C>T p.S328= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV53851065; called by muse, mutect2, varscan2
- SPATA17 | c.729C>T p.P243= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV65121906, COSV65124603; called by muse, mutect2, varscan2
- SPRR3 | c.60G>A p.Q20= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV54880482; called by muse, mutect2, varscan2
- SSTR5 | c.9C>T p.P3= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV53512887; called by muse, mutect2, varscan2
- SYNDIG1L | c.165G>A p.L55= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59048044; called by muse, mutect2, varscan2
- TAS1R2 | c.2481C>T p.F827= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV64746105; called by muse, mutect2, varscan2
- TBC1D1 | c.27G>A p.R9= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV54723488; called by muse, mutect2, varscan2
- TCFL5 | c.1032G>C p.R344= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV99415609; called by muse, mutect2, varscan2
- TECPR1 | c.849C>T p.I283= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs770318671, COSV65782976; called by muse, mutect2, varscan2
- TMEM131L | c.3657G>A p.K1219= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV53647953; called by muse, mutect2, varscan2
- TMEM132B | c.1341C>T p.V447= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as rs773751171, COSV54747870; called by muse, mutect2, varscan2
- TMEM143 | c.861C>T p.V287= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV53157942; called by muse, mutect2, varscan2
- TMEM270 | c.331C>T p.L111= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs782013187, COSV57639292; called by muse, mutect2, varscan2
- TMPRSS7 | c.1164C>T p.S388= (on ENST00000452346; = p.S262= on NM_001042575.2) | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV69981930; called by muse, mutect2, varscan2
- TNFSF11 | c.468G>A p.K156= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1360861197, COSV53478719, COSV99520494; called by muse, mutect2, varscan2
- TP53BP2 | c.2286G>A p.R762= (on ENST00000343537 / NM_001031685.3; = p.R633= on NM_005426.2) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV59068217; called by muse, mutect2, varscan2
- TRBV24-1 | c.90G>A p.R30= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- TRHDE | c.2535G>A p.R845= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV53848210; called by muse, mutect2, varscan2
- TTLL8 | c.276G>A p.E92= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56729949; called by muse, mutect2, varscan2
- TTN | c.1818G>A p.R606= (on ENST00000591111; = p.R560= on NM_003319.4) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV60001972; called by muse, mutect2, varscan2
- VPS35L | c.1131G>A p.L377= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51987346; called by muse, mutect2, varscan2
- VWA7 | c.300C>T p.F100= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV63304941; called by muse, mutect2, varscan2
- WNK1 | c.2472C>T p.F824= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs1418995609, COSV100266458; called by muse, mutect2, varscan2
- XAB2 | c.1464C>T p.S488= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs750639458, COSV50343916; called by muse, mutect2, varscan2
- XKR4 | c.1314G>A p.G438= | Silent (SNP) | VAF 69/187 reads (37%) | catalogued as COSV59329176; called by muse, mutect2, varscan2
- ZCWPW2 | c.759T>C p.D253= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV67500069; called by muse, mutect2
- ZFP42 | c.669G>A p.G223= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV58818436; called by muse, mutect2, varscan2
- ZNF335 | c.2958C>T p.S986= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV59819092; called by muse, mutect2, varscan2
- ZNF536 | c.189C>T p.S63= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV62829506; called by muse, mutect2, varscan2
- ZNF544 | c.1701G>A p.Q567= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV54137113, COSV99516883; called by muse, mutect2, varscan2
- ZNF99 | c.1104C>T p.P368= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101233907, COSV68056170; called by muse, mutect2, varscan2
- ZSCAN5B | c.762G>A p.G254= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV62000687; called by muse, mutect2, varscan2
- ABHD5 | c.774-616C>T | Intron (SNP) | VAF 20/70 reads (29%) | catalogued as rs775943260, COSV68904807; called by muse, mutect2, varscan2
- C7orf65 | n.77C>T | RNA (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847801 G>A | 5'Flank (SNP) | VAF 31/171 reads (18%) | catalogued as rs764613144; called by muse, mutect2, varscan2
- MUCL3 | c.947-73G>A | Intron (SNP) | VAF 20/57 reads (35%) | catalogued as COSV58518215; called by muse, mutect2, varscan2
- NACA | c.71-1905C>T | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as rs1265120326, COSV100771119; called by muse, mutect2, varscan2
- PDPN | c.-110C>T | 5'UTR (SNP) | VAF 9/35 reads (26%) | catalogued as rs142084255, COSV53849445; called by muse, mutect2
- RIMS2 | c.1692+254C>T | Intron (SNP) | VAF 31/59 reads (53%) | catalogued as COSV99163359; called by muse, mutect2, varscan2
- RIMS2 | c.1692+255C>T | Intron (SNP) | VAF 31/60 reads (52%) | catalogued as COSV99163364; called by muse, mutect2, varscan2
- RPL26P30 | n.827G>A | RNA (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- SDR16C5 | c.*2G>A | 3'UTR (SNP) | VAF 40/191 reads (21%) | catalogued as COSV100373852; called by muse, mutect2, varscan2
- SNORD114-31 | n.60G>A | RNA (SNP) | VAF 16/50 reads (32%) | catalogued as rs748683389; called by muse, mutect2, varscan2
- TRAK1 | c.1963+160C>T | Intron (SNP) | VAF 39/164 reads (24%) | catalogued as COSV100409806; called by muse, mutect2, varscan2
- TTN | c.10361-5213G>A | Intron (SNP) | VAF 21/72 reads (29%) | catalogued as rs767658020, COSV100598441; called by muse, mutect2, varscan2
